Gene-level copy-number profile of tumor specimen TCGA-43-2578-01A from TCGA case TCGA-43-2578, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.5 years (21,747 days).
Specimen TCGA-43-2578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4fa4c89a-1d6a-4ac6-b854-36fee268fa0f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-2578-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6d0ef25-6200-4e2f-9dee-3da4cadf1d80

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 2: 760; copy number 3: 18,113; copy number 4: 8,862; copy number 5: 10,014; copy number 6: 12,307; copy number 7: 2,803; copy number 8: 1,736; copy number 9: 2,118; copy number 10: 2,649; copy number 12: 23; copy number 13: 157; copy number 17: 104; copy number 19: 151.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-2578-01A-01D-1969-01): tumor purity 0.59, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:62,071,752–62,510,771, 8 genes: ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11.
- chr21:19,593,841–20,258,820, 6 genes: RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 9,741 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:164,343,005–178,548,889, 282 genes, copy number 7 (broad region; genes not listed).
- chr2:30,722,771–30,820,542, 1 gene, copy number 7 (within-gene range 4–7): CAPN13.
- chr2:30,887,626–48,780,895, 301 genes, copy number 7 (broad region; genes not listed).
- chr2:177,603,089–177,618,742, 2 genes, copy number 8: AC073834.1, TTC30A.
- chr2:177,653,419–177,723,289, 1 gene, copy number 8: PDE11A-AS1.
- chr3:11,745–6,736,750, 62 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:110,551,845–198,222,513, 1,588 genes, copy number 9–13 (broad region; genes not listed).
- chr4:51,843,000–62,078,335, 151 genes, copy number 19 (within-gene range 0–19) (broad region; genes not listed).
- chr5:58,198–12,804,363, 245 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr6:167,607–31,516,211, 823 genes, copy number 8 (broad region; genes not listed).
- chr6:100,427,118–105,083,332, 25 genes, copy number 8 (within-gene range 6–8): SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2, GRIK2, ACTG1P18, AP002528.1, AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P.
- chr6:122,996,235–147,953,937, 352 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr6:148,478,693–170,738,536, 408 genes, copy number 10 (broad region; genes not listed).
- chr7:98,794,718–153,449,875, 1,181 genes, copy number 7 (broad region; genes not listed).
- chr8:32,911,493–145,066,685, 1,759 genes, copy number 7–17 (broad region; genes not listed).
- chr9:14,475–1,164,867, 28 genes, copy number 7–12: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14.
- chr10:112,283,400–115,948,999, 57 genes, copy number 9 (within-gene range 6–9): TECTB, MIR6715B, MIR6715A, GUCY2GP, ACSL5, AL157786.1, ZDHHC6, VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1.
- chr12:9,985,642–13,387,167, 122 genes, copy number 8 (broad region; genes not listed).
- chr12:13,440,884–13,547,582, 4 genes, copy number 8: RNA5SP353, RNU6-590P, AC007527.1, AC007527.2.
- chr17:17,476,994–22,706,703, 272 genes, copy number 9 (broad region; genes not listed).
- chr17:71,011,997–83,095,122, 462 genes, copy number 8 (broad region; genes not listed).
- chr19:35,042,902–43,418,597, 449 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:7,831,798–43,727,002, 709 genes, copy number 7–9 (broad region; genes not listed).
- chr20:47,160,838–63,843,915, 382 genes, copy number 9 (broad region; genes not listed).
- chr21:20,355,748–21,543,329, 10 genes, copy number 7 (within-gene range 3–7): RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1.
- chr21:27,954,922–30,440,945, 52 genes, copy number 8: AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1, LINC00189, BACH1, GAPDHP14, BACH1-IT1, AP000240.1, BACH1-AS1, BACH1-IT2, BACH1-IT3, GRIK1, AP000238.1, GRIK1-AS1, AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1.
- chr21:40,010,999–41,282,530, 13 genes, copy number 9 (within-gene range 6–9): DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3, AL773573.1, LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
